Somatic mutation profile of tumor specimen HCM-SANG-0297-C15-01A (aliquot HCM-SANG-0297-C15-01A-01D-A79M-36) from HCMI case HCM-SANG-0297-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G2.
Specimen HCM-SANG-0297-C15-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a65e8db6-1e86-4b3e-8791-d572eda8acdc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-SANG-0297-C15-10A (Blood Derived Normal), aliquot HCM-SANG-0297-C15-10A-01D-A79M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/152d0c5f-2c1f-45ae-bdf4-4453e3472e9f

The open-access MAF lists 155 somatic variants for this specimen: 110 protein-altering or splice-affecting, 41 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 94, Silent 41, Nonsense Mutation 5, Frame Shift Del 4, Frame Shift Ins 3, Splice Region 2, Intron 1, 3'UTR 1, RNA 1, 5'Flank 1, Splice Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB4 | c.2393T>C p.L798P | Missense Mutation (SNP) | VAF 103/251 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100725903, COSV61483358, COSV61493836; called by muse, mutect2, varscan2
- ADGRB1 | c.3541G>A p.V1181I | Missense Mutation (SNP) | VAF 104/389 reads (27%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.956); catalogued as rs772937459; called by muse, mutect2, varscan2
- APC2 | c.4564G>A p.A1522T | Missense Mutation (SNP) | VAF 194/804 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs375010507; called by muse, varscan2
- APLP2 | c.1198C>T p.R400W | Missense Mutation (SNP) | VAF 72/202 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1212536922, COSV53842237; called by muse, mutect2, varscan2
- BICRA | c.3667G>A p.G1223S | Missense Mutation (SNP) | VAF 44/594 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs766601975; called by muse, mutect2
- BTBD10 | c.283C>T p.R95* | Nonsense Mutation (SNP) | VAF 34/163 reads (21%) | catalogued as COSV99533629; called by muse, mutect2, varscan2
- C10orf53 | c.223G>A p.D75N | Missense Mutation (SNP) | VAF 63/232 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.985); catalogued as rs369717123; called by muse, mutect2, varscan2
- C4orf50 | c.269G>A p.R90H (on ENST00000324058; = p.R1322H on NM_001364689.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 59/403 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs776133301, COSV100136140; called by muse, mutect2
- CACNA2D2 | c.3036C>G p.S1012R (on ENST00000479441 / NM_001174051.3; = p.S1005R on NM_006030.4) | Missense Mutation (SNP) | VAF 145/493 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1208916332; called by muse, mutect2, varscan2
- CDH10 | c.2198T>G p.L733R | Missense Mutation (SNP) | VAF 67/274 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100050052; called by muse, mutect2, varscan2
- CDKN2A | c.68G>T p.G23V | Missense Mutation (SNP) | VAF 187/665 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM980322, COSV58684053, COSV58729667; called by muse, mutect2, varscan2
- CPSF3 | c.1875C>G p.D625E | Missense Mutation (SNP) | VAF 74/195 reads (38%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as COSV99432476; called by muse, mutect2
- DSG3 | c.883G>A p.E295K | Missense Mutation (SNP) | VAF 98/233 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99934706; called by muse, mutect2, varscan2
- E2F4 | c.767C>T p.A256V | Missense Mutation (SNP) | VAF 23/362 reads (6%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs757259236; called by muse, mutect2
- EYS | c.6485A>C p.K2162T | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT tolerated (0.59); PolyPhen benign (0.009); catalogued as rs1039415909; called by muse, varscan2
- FREM1 | c.4465C>T p.R1489W | Missense Mutation (SNP) | VAF 42/480 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs1029084142, COSV66526194; called by muse, mutect2
- GDF2 | c.508G>A p.V170M | Missense Mutation (SNP) | VAF 20/576 reads (3%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs201972913; called by muse, mutect2
- GORASP1 | c.239G>A p.R80H | Missense Mutation (SNP) | VAF 203/524 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766833329, COSV57188379; called by muse, mutect2, varscan2
- HDX | c.2021C>T p.T674I | Missense Mutation (SNP) | VAF 21/174 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs769373598; called by muse, mutect2
- HP | c.789G>A p.M263I | Missense Mutation (SNP) | VAF 21/240 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as rs769677847; called by muse, mutect2
- HYPK | c.344C>T p.A115V | Missense Mutation (SNP) | VAF 175/293 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as rs372106020; called by muse, mutect2, varscan2
- IGFALS | c.1637C>T p.A546V | Missense Mutation (SNP) | VAF 48/538 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs202125685; called by muse, mutect2
- ITGA6 | c.2051G>A p.R684Q (on ENST00000442250; = p.R645Q on NM_000210.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 63/159 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as rs190444302; called by muse, mutect2, varscan2
- KDM6A | c.1792A>G p.I598V | Missense Mutation (SNP) | VAF 223/322 reads (69%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0); catalogued as rs762004743, COSV65039921; called by muse, mutect2, varscan2
- MEGF6 | c.3427G>A p.V1143I | Missense Mutation (SNP) | VAF 77/459 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.047); catalogued as rs942388766, COSV99621435; called by muse, mutect2, varscan2
- MMP26 | c.450G>T p.K150N | Missense Mutation (SNP) | VAF 30/231 reads (13%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.564); catalogued as rs771890155; called by mutect2, varscan2
- NLRP5 | c.2386C>T p.R796W | Missense Mutation (SNP) | VAF 54/468 reads (12%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as rs144876069, COSV66761951; called by muse, mutect2, varscan2
- NPM2 | c.182G>A p.R61H | Missense Mutation (SNP) | VAF 109/255 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV57075073; called by muse, mutect2, varscan2
- P4HTM | c.157C>T p.R53C | Missense Mutation (SNP) | VAF 238/598 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.759); catalogued as rs372623573; called by muse, mutect2, varscan2
- PCDH11Y | c.3316G>A p.D1106N | Missense Mutation (SNP) | VAF 49/82 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99291559; called by muse, mutect2, varscan2
- PTPN21 | c.2051G>A p.R684Q | Missense Mutation (SNP) | VAF 101/549 reads (18%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1351469317; called by muse, mutect2, varscan2
- RELB | c.362C>T p.P121L | Missense Mutation (SNP) | VAF 160/532 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.04); catalogued as rs376331542, COSV55512134; called by muse, mutect2, varscan2
- RIMS2 | c.2943C>A p.S981R (on ENST00000666250 / NM_001348490.2; = p.S789R on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.844); catalogued as rs1251912528; called by muse, mutect2, varscan2
- SLC2A6 | c.1012C>T p.R338C | Missense Mutation (SNP) | VAF 101/462 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs878916227; called by muse, mutect2, varscan2
- SLCO1C1 | c.923C>A p.S308Y | Missense Mutation (SNP) | VAF 28/168 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.285); catalogued as COSV56875151; called by muse, mutect2, varscan2
- SYNE1 | c.217C>A p.Q73K | Missense Mutation (SNP) | VAF 68/268 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.154); catalogued as rs774912325, COSV55053978; called by muse, varscan2
- TP53 | c.956del p.K319Rfs*26 | Frame Shift Del (DEL) | VAF 95/287 reads (33%) | catalogued as COSV53486415; called by mutect2, pindel, varscan2
- UBQLN3 | c.433T>G p.L145V | Missense Mutation (SNP) | VAF 116/480 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.118); catalogued as COSV104411257; called by muse, mutect2, varscan2
- UBR5 | c.7906del p.R2636Gfs*10 | Frame Shift Del (DEL) | VAF 57/279 reads (20%) | catalogued as COSV55290368; called by mutect2, pindel, varscan2
- UNC79 | c.6247C>T p.R2083C (on ENST00000393151 / NM_001346218.2; = p.R1906C on NM_020818.5) | Missense Mutation (SNP) | VAF 47/444 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774094564, COSV56376638; called by muse, mutect2, varscan2
- USH2A | c.2348A>C p.N783T | Missense Mutation (SNP) | VAF 17/174 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.502); catalogued as COSV56327866, COSV56347503; called by muse, mutect2, varscan2
- ZFP28 | c.739C>G p.P247A | Missense Mutation (SNP) | VAF 73/201 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.184); catalogued as rs544442408, COSV100019783; called by muse, mutect2, varscan2
- ZIC2 | c.928G>A p.E310K | Missense Mutation (SNP) | VAF 46/605 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.094); catalogued as rs778049889, CM091702; called by muse, mutect2
- ZNF43 | c.516dup p.L173Tfs*21 | Frame Shift Ins (INS) | VAF 26/148 reads (18%) | catalogued as rs748612562; called by mutect2, varscan2
- ZNF469 | c.7179C>A p.D2393E (on ENST00000437464; = p.D2421E on NM_001367624.2) | Missense Mutation (SNP) | VAF 20/646 reads (3%) | SIFT tolerated (0.85); PolyPhen benign (0.061); catalogued as rs1213989862; called by muse, mutect2
- APBB2 | c.181A>G p.S61G | Missense Mutation (SNP) | VAF 68/356 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- C11orf53 | c.495C>G p.D165E | Missense Mutation (SNP) | VAF 98/299 reads (33%) | SIFT tolerated (0.48); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- CABS1 | c.670A>C p.S224R | Missense Mutation (SNP) | VAF 35/264 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CCND2 | c.856G>A p.D286N | Missense Mutation (SNP) | VAF 10/240 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); called by muse, mutect2
- CFAP54 | c.8854T>A p.L2952I | Missense Mutation (SNP) | VAF 14/189 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.412); called by muse, mutect2
- CNKSR2 | c.941A>C p.K314T | Missense Mutation (SNP) | VAF 92/141 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- CPZ | c.306T>G p.C102W (on ENST00000360986 / NM_001014447.3; = p.C91W on NM_003652.3) | Missense Mutation (SNP) | VAF 66/659 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CYP24A1 | c.379C>A p.Q127K | Missense Mutation (SNP) | VAF 33/752 reads (4%) | SIFT tolerated (0.36); PolyPhen benign (0.027); called by muse, mutect2
- DIAPH2 | c.2444T>A p.I815K | Missense Mutation (SNP) | VAF 31/153 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- DNAH8 | c.3278A>G p.K1093R | Missense Mutation (SNP) | VAF 60/236 reads (25%) | SIFT tolerated (0.5); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- DYRK2 | c.484C>T p.Q162* (on ENST00000344096 / NM_006482.3; = p.Q89* on NM_003583.4) | Nonsense Mutation (SNP) | VAF 92/338 reads (27%) | called by muse, mutect2, varscan2
- EGLN3 | c.668A>C p.K223T | Missense Mutation (SNP) | VAF 74/244 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ENTPD8 | c.106C>T p.L36F | Missense Mutation (SNP) | VAF 120/386 reads (31%) | SIFT tolerated (0.68); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- ERMN | c.450A>T p.K150N | Missense Mutation (SNP) | VAF 108/275 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- FAT2 | c.7906A>C p.I2636L | Missense Mutation (SNP) | VAF 121/281 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- FAT2 | c.7811T>G p.V2604G | Missense Mutation (SNP) | VAF 138/312 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- GALNT17 | c.1325A>G p.K442R | Missense Mutation (SNP) | VAF 100/422 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- HERC2 | c.4544T>C p.F1515S | Missense Mutation (SNP) | VAF 29/304 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- HIVEP1 | c.1249A>T p.K417* | Nonsense Mutation (SNP) | VAF 20/313 reads (6%) | called by muse, mutect2
- IRF1 | c.268G>C p.D90H | Missense Mutation (SNP) | VAF 48/351 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ISCU | c.319_320insGT p.E107Gfs*4 (on ENST00000311893 / NM_213595.4; = p.E82Gfs*4 on NM_014301.4) | Frame Shift Ins (INS) | VAF 42/450 reads (9%) | called by mutect2, pindel
- LDLRAD3 | c.362A>C p.K121T | Missense Mutation (SNP) | VAF 114/401 reads (28%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.75); called by muse, mutect2, varscan2
- LIMD1 | c.490C>T p.Q164* | Nonsense Mutation (SNP) | VAF 67/436 reads (15%) | called by muse, mutect2, varscan2
- MMP16 | c.339T>G p.F113L | Missense Mutation (SNP) | VAF 8/262 reads (3%) | SIFT tolerated (0.74); PolyPhen benign (0.017); called by muse, mutect2
- MPRIP | c.2540C>T p.A847V | Missense Mutation (SNP) | VAF 142/328 reads (43%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- MYT1L | c.266A>G p.E89G | Missense Mutation (SNP) | VAF 48/409 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- NAA35 | c.627G>A p.K209= | Splice Region (SNP) | VAF 31/120 reads (26%) | called by muse, mutect2, varscan2
- NEK8 | c.2049A>G p.R683= | Splice Region (SNP) | VAF 51/328 reads (16%) | called by muse, mutect2, varscan2
- NOXRED1 | c.496G>T p.V166L | Missense Mutation (SNP) | VAF 32/295 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- NPHP4 | c.783G>T p.E261D | Missense Mutation (SNP) | VAF 37/212 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- NRG3 | c.5G>T p.S2I | Missense Mutation (SNP) | VAF 21/133 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.883); called by muse, varscan2
- PALM3 | c.1116_1141del p.D373Gfs*26 (on ENST00000340790; = p.D388Gfs*26 on NM_001145028.2) | Frame Shift Del (DEL) | VAF 76/838 reads (9%) | called by mutect2, pindel
- PCDH11X | c.824A>T p.D275V | Missense Mutation (SNP) | VAF 9/264 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PDGFRA | c.348C>G p.H116Q | Missense Mutation (SNP) | VAF 25/145 reads (17%) | SIFT tolerated (0.53); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- PKHD1L1 | c.11982A>C p.E3994D | Missense Mutation (SNP) | VAF 30/358 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.075); called by muse, mutect2
- PLCH1 | c.1021C>T p.R341C (on ENST00000340059 / NM_001130960.2; = p.R353C on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/261 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PPP1R42 | c.305dup p.G103Rfs*22 | Frame Shift Ins (INS) | VAF 64/250 reads (26%) | called by mutect2, pindel, varscan2
- PPP4R1 | c.2140C>G p.L714V (on ENST00000400556 / NM_001042388.3; = p.L697V on NM_005134.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 67/447 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- PRAMEF1 | c.1009C>A p.L337I | Missense Mutation (SNP) | VAF 50/400 reads (13%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PRAMEF4 | c.863A>T p.D288V | Missense Mutation (SNP) | VAF 45/240 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- PRKDC | c.5071C>T p.Q1691* | Nonsense Mutation (SNP) | VAF 25/230 reads (11%) | called by muse, mutect2
- PTPN5 | c.70G>A p.D24N | Missense Mutation (SNP) | VAF 115/346 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.57); called by muse, mutect2, varscan2
- PXDNL | c.2718A>T p.E906D | Missense Mutation (SNP) | VAF 127/435 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- RAB12 | c.202T>G p.C68G | Missense Mutation (SNP) | VAF 55/743 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0.028); called by muse, mutect2
- RBM23 | c.865A>G p.I289V (on ENST00000359890 / NM_001077351.2; = p.I273V on NM_018107.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 62/194 reads (32%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- RORA | c.416C>T p.S139F (on ENST00000335670 / NM_134261.3; = p.S164F on NM_002943.3) | Missense Mutation (SNP) | VAF 51/208 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SHROOM2 | c.65A>G p.D22G | Missense Mutation (SNP) | VAF 96/483 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.535); called by muse, mutect2, varscan2
- SLC12A5 | c.1549_1551del p.S517del (on ENST00000454036 / NM_001134771.2; = p.S494del on NM_020708.5) | In Frame Del (DEL) | VAF 115/647 reads (18%) | called by mutect2, pindel, varscan2
- SLC4A2 | c.2410G>A p.A804T | Missense Mutation (SNP) | VAF 46/446 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- SOX1 | c.686C>T p.A229V | Missense Mutation (SNP) | VAF 82/778 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.286); called by muse, varscan2
- SRCAP | c.6490T>A p.Y2164N | Missense Mutation (SNP) | VAF 119/454 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SYMPK | c.1329A>C p.E443D | Missense Mutation (SNP) | VAF 93/332 reads (28%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- SYNE2 | c.8126T>C p.L2709S | Missense Mutation (SNP) | VAF 29/260 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TAL1 | c.397G>T p.G133C | Missense Mutation (SNP) | VAF 71/502 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.555); called by muse, mutect2, varscan2
- TNXB | c.1730A>C p.E577A | Missense Mutation (SNP) | VAF 129/570 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- TRAPPC12 | c.2087A>G p.N696S | Missense Mutation (SNP) | VAF 58/364 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UNC93B1 | c.996_1041del p.F332Lfs*102 | Frame Shift Del (DEL) | VAF 84/399 reads (21%) | called by mutect2, pindel, varscan2
- UTRN | c.5247G>T p.L1749F | Missense Mutation (SNP) | VAF 36/148 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- VAV3 | c.1618C>G p.Q540E | Missense Mutation (SNP) | VAF 38/200 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- ZBTB1 | c.1898G>A p.R633K (on ENST00000554015 / NM_001123329.1; = p.S633N on NM_014950.3) | Missense Mutation (SNP) | VAF 93/261 reads (36%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- ZBTB7A | c.1375G>A p.V459M | Missense Mutation (SNP) | VAF 192/572 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, varscan2
- ZFAND4 | c.1259G>T p.C420F | Missense Mutation (SNP) | VAF 25/341 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.017); called by muse, mutect2
- ZNF420 | c.10-1G>C p.X4_splice | Splice Site (SNP) | VAF 32/182 reads (18%) | called by muse, mutect2, varscan2
- ZNF7 | c.1457A>C p.Q486P | Missense Mutation (SNP) | VAF 75/323 reads (23%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- ZNF773 | c.394G>T p.V132F | Missense Mutation (SNP) | VAF 46/331 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAMTSL3 | c.1527C>T p.R509= | Silent (SNP) | VAF 68/299 reads (23%) | catalogued as rs564700676, COSV54440714; called by muse, mutect2, varscan2
- ARSA | c.759G>T p.L253= | Silent (SNP) | VAF 185/403 reads (46%) | catalogued as COSV53350273; called by muse, mutect2, varscan2
- BRSK2 | c.888G>A p.E296= | Silent (SNP) | VAF 149/450 reads (33%) | catalogued as COSV100373196; called by muse, mutect2, varscan2
- CAMK2D | c.921T>G p.T307= | Silent (SNP) | VAF 66/197 reads (34%) | called by muse, mutect2, varscan2
- CCDC168 | c.13992A>C p.L4664= | Silent (SNP) | VAF 40/358 reads (11%) | called by muse, mutect2, varscan2
- CDH23 | c.6384T>C p.G2128= | Silent (SNP) | VAF 90/368 reads (24%) | catalogued as COSV99819412; called by muse, mutect2, varscan2
- CEP350 | c.7053C>T p.H2351= | Silent (SNP) | VAF 62/234 reads (26%) | catalogued as rs749229723; called by muse, mutect2, varscan2
- CRTC3 | c.84G>A p.E28= | Silent (SNP) | VAF 50/463 reads (11%) | called by muse, mutect2, varscan2
- DAPK2 | c.258C>A p.V86= | Silent (SNP) | VAF 245/405 reads (60%) | called by muse, mutect2, varscan2
- DGKG | c.1035C>T p.S345= | Silent (SNP) | VAF 131/466 reads (28%) | catalogued as rs749215718, COSV53965863; called by muse, mutect2, varscan2
- DPY19L1 | c.777G>A p.Q259= | Silent (SNP) | VAF 81/197 reads (41%) | catalogued as rs1354377147; called by muse, mutect2, varscan2
- EHD1 | c.165C>T p.F55= | Silent (SNP) | VAF 224/477 reads (47%) | called by muse, mutect2, varscan2
- FBXO43 | c.930T>C p.I310= | Silent (SNP) | VAF 24/445 reads (5%) | catalogued as rs749803814; called by muse, mutect2
- FNDC1 | c.1737C>T p.P579= | Silent (SNP) | VAF 48/481 reads (10%) | catalogued as rs1477141480, COSV51929781; called by muse, mutect2, varscan2
- FREM3 | c.3709C>A p.R1237= | Silent (SNP) | VAF 87/405 reads (21%) | called by muse, mutect2, varscan2
- GFOD1 | c.780C>T p.A260= | Silent (SNP) | VAF 72/383 reads (19%) | catalogued as rs754200124; called by muse, mutect2, varscan2
- IGKV1D-17 | c.270G>A p.G90= | Silent (SNP) | VAF 105/286 reads (37%) | called by muse, mutect2, varscan2
- KCNK4 | c.786C>T p.R262= | Silent (SNP) | VAF 29/361 reads (8%) | catalogued as rs570855718; called by muse, mutect2
- KCTD8 | c.96C>T p.A32= | Silent (SNP) | VAF 86/407 reads (21%) | catalogued as rs769210211, COSV100760252; called by muse, mutect2, varscan2
- KMT2D | c.13491G>A p.G4497= | Silent (SNP) | VAF 32/506 reads (6%) | called by muse, mutect2
- LRRC4B | c.1497C>T p.P499= | Silent (SNP) | VAF 213/590 reads (36%) | catalogued as rs1434657460, COSV100975841, COSV65350297; called by muse, mutect2, varscan2
- MAP1A | c.1788C>T p.V596= | Silent (SNP) | VAF 32/436 reads (7%) | called by muse, mutect2
- NFATC4 | c.2196C>T p.C732= | Silent (SNP) | VAF 154/428 reads (36%) | catalogued as rs141569636, COSV51603826; called by muse, mutect2, varscan2
- NLRP12 | c.882C>T p.D294= | Silent (SNP) | VAF 112/342 reads (33%) | catalogued as rs147080557, CM1111600; called by muse, mutect2, varscan2
- NPAS3 | c.2457C>T p.A819= (on ENST00000356141 / NM_001164749.2; = p.A787= on NM_022123.3) | Silent (SNP) | VAF 33/536 reads (6%) | catalogued as rs771394629; called by muse, mutect2
- NPHS1 | c.2259C>T p.V753= | Silent (SNP) | VAF 111/305 reads (36%) | catalogued as rs766951918; called by muse, mutect2, varscan2
- OBSCN | c.17463G>A p.P5821= | Silent (SNP) | VAF 148/419 reads (35%) | catalogued as rs765645372; called by muse, mutect2, varscan2
- OR51M1 | c.687C>T p.S229= | Silent (SNP) | VAF 131/469 reads (28%) | called by muse, mutect2, varscan2
- OR6F1 | c.144G>A p.L48= | Silent (SNP) | VAF 44/309 reads (14%) | called by muse, mutect2, varscan2
- PDGFC | c.277A>C p.R93= | Silent (SNP) | VAF 28/160 reads (18%) | called by muse, mutect2, varscan2
- PRDM2 | c.378T>C p.T126= | Silent (SNP) | VAF 28/147 reads (19%) | called by muse, mutect2, varscan2
- RBM19 | c.1497G>A p.K499= | Silent (SNP) | VAF 189/360 reads (53%) | catalogued as rs1351942891; called by muse, mutect2, varscan2
- SLC12A8 | c.255C>T p.A85= | Silent (SNP) | VAF 84/499 reads (17%) | catalogued as rs1190817586; called by muse, mutect2, varscan2
- SMOC2 | c.837G>A p.P279= (on ENST00000356284 / NM_001166412.2; = p.P290= on NM_022138.3) | Silent (SNP) | VAF 106/402 reads (26%) | catalogued as rs376609544; called by muse, mutect2, varscan2
- SOWAHA | c.594G>A p.P198= | Silent (SNP) | VAF 102/695 reads (15%) | called by muse, mutect2, varscan2
- SOX18 | c.750G>A p.A250= | Silent (SNP) | VAF 99/1087 reads (9%) | called by muse, mutect2
- ST8SIA4 | c.868A>C p.R290= | Silent (SNP) | VAF 32/129 reads (25%) | catalogued as COSV51508323, COSV51509997; called by muse, mutect2, varscan2
- TFAP2E | c.357G>A p.P119= | Silent (SNP) | VAF 140/665 reads (21%) | catalogued as rs774890111; called by muse, mutect2, varscan2
- TRIM16L | c.840G>A p.G280= | Silent (SNP) | VAF 112/300 reads (37%) | called by muse, mutect2, varscan2
- UNC13A | c.1926C>T p.F642= | Silent (SNP) | VAF 119/483 reads (25%) | catalogued as rs780011051, COSV53211999; called by muse, mutect2, varscan2
- WDFY4 | c.1950G>T p.L650= | Silent (SNP) | VAF 47/440 reads (11%) | called by muse, mutect2, varscan2
- AL121718.1 | n.317G>A | RNA (SNP) | VAF 36/146 reads (25%) | catalogued as rs964782907; called by muse, mutect2, varscan2
- MATK | chr19:3789296 T>A | 5'Flank (SNP) | VAF 23/357 reads (6%) | called by muse, mutect2
- SLC9A9 | c.*791C>A | 3'UTR (SNP) | VAF 58/285 reads (20%) | catalogued as rs556404248; called by muse, mutect2, varscan2
- SRP9 | c.142-181T>A | Intron (SNP) | VAF 16/226 reads (7%) | called by muse, mutect2
